Somatic mutation profile of tumor specimen TCGA-CG-4444-01A (aliquot TCGA-CG-4444-01A-01D-1158-08) from TCGA case TCGA-CG-4444, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 76.4 years (27,912 days).
Specimen TCGA-CG-4444-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b75d84c5-bfc5-47e8-a097-912795845581.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CG-4444-10A (Blood Derived Normal), aliquot TCGA-CG-4444-10A-01D-1158-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/41a24d3a-c9fd-4c86-9d4a-0f08f10b4c34

The open-access MAF lists 178 somatic variants for this specimen: 130 protein-altering or splice-affecting, 46 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 120, Silent 46, Nonsense Mutation 5, Splice Site 2, Frame Shift Del 2, RNA 1, Nonstop Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EYA4 | c.455T>G p.L152R | Missense Mutation (SNP) | VAF 55/252 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62044745, COSV62052190, COSV62055739; called by muse, mutect2, varscan2
- RIMS1 | c.211A>G p.R71G | Missense Mutation (SNP) | VAF 8/103 reads (8%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV53441304, COSV53444045, COSV53451865; called by muse, mutect2
- SMAD2 | c.962G>A p.R321Q | Missense Mutation (SNP) | VAF 14/105 reads (13%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV50994862; called by muse, mutect2, varscan2
- TENT5D | c.205A>C p.S69R | Missense Mutation (SNP) | VAF 13/59 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57634984, COSV57635195, COSV57638952; called by muse, mutect2, varscan2
- TP53 | c.535C>T p.H179Y | Missense Mutation (SNP) | VAF 29/48 reads (60%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs587780070, CM067054, COSV52662617, COSV52668276, COSV52699993; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.7522T>G p.F2508V (on ENST00000272895 / NM_173076.3; = p.F2190V on NM_015657.3) | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99788156; called by muse, mutect2, varscan2
- ADA2 | c.1508A>C p.K503T (on ENST00000262607; = p.K262T on NM_177405.3) | Missense Mutation (SNP) | VAF 102/469 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.013); catalogued as COSV52832792, COSV99376444; called by muse, varscan2
- ADCYAP1R1 | c.1004T>G p.L335R | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58445481; called by muse, mutect2, varscan2
- AGBL1 | c.614A>T p.N205I | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.664); catalogued as COSV69808342; called by muse, mutect2, varscan2
- AGBL2 | c.1000G>C p.V334L | Missense Mutation (SNP) | VAF 21/152 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV54094237; called by muse, mutect2, varscan2
- AKAP7 | c.698A>C p.K233T | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.743); catalogued as COSV53836581; called by muse, mutect2, varscan2
- APOB | c.9290A>C p.K3097T | Missense Mutation (SNP) | VAF 20/217 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV51938840, COSV99264964; called by muse, mutect2
- BCLAF1 | c.711T>G p.S237R | Missense Mutation (SNP) | VAF 23/390 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.975); catalogued as rs1404068444, COSV62144417; called by muse, mutect2
- C16orf78 | c.80G>A p.R27H | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as rs144505396; called by muse, mutect2, varscan2
- C1orf127 | c.2033G>A p.S678N | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.895); catalogued as COSV65436721; called by muse, mutect2, varscan2
- C1orf94 | c.1792T>G p.F598V (on ENST00000488417 / NM_001134734.2; = p.F408V on NM_032884.5) | Missense Mutation (SNP) | VAF 19/136 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV64914296, COSV64914459; called by muse, mutect2, varscan2
- CCDC3 | c.387T>G p.N129K | Missense Mutation (SNP) | VAF 41/165 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV66560940; called by muse, mutect2, varscan2
- CCDC39 | c.341A>C p.K114T | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as COSV56490066; called by muse, mutect2
- CHRNA5 | c.917C>T p.S306F | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55139771; called by muse, mutect2, varscan2
- CILP | c.3555A>C p.*1185Yext*14 | Nonstop Mutation (SNP) | VAF 14/39 reads (36%) | catalogued as COSV56026612; called by muse, mutect2, varscan2
- CILP | c.1142A>C p.D381A | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV56026624; called by muse, mutect2, varscan2
- CNKSR2 | c.3049G>C p.D1017H | Missense Mutation (SNP) | VAF 50/69 reads (72%) | SIFT tolerated (0.05); PolyPhen benign (0.188); catalogued as COSV65278631; called by muse, mutect2, varscan2
- CNTNAP2 | c.946T>G p.F316V | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.56); catalogued as COSV62229646; called by muse, mutect2, varscan2
- COL12A1 | c.9157C>G p.P3053A | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as COSV59403107; called by muse, mutect2
- CPS1 | c.3017T>G p.L1006R | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.702); catalogued as COSV51819105; called by muse, mutect2, varscan2
- CRACD | c.2657C>T p.A886V | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1240672328, COSV51714602; called by muse, mutect2, varscan2
- CTNND2 | c.3575A>C p.K1192T | Missense Mutation (SNP) | VAF 21/148 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100481783, COSV58877118; called by muse, mutect2, varscan2
- DCAF12L2 | c.122A>C p.K41T | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV100758441; called by muse, varscan2
- DCBLD1 | c.600C>G p.C200W | Missense Mutation (SNP) | VAF 7/196 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51644250; called by muse, mutect2
- DDO | c.110A>C p.K37T | Missense Mutation (SNP) | VAF 27/277 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.209); catalogued as COSV64470204; called by muse, mutect2
- DHRS9 | c.500G>A p.G167D | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59140982; called by muse, mutect2, varscan2
- DMD | c.1331A>C p.N444T | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.06); catalogued as rs1385774389, COSV55890592; called by muse, mutect2, varscan2
- DOCK2 | c.2719C>T p.H907Y | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); catalogued as COSV99910159; called by muse, varscan2
- DPYSL5 | c.716C>A p.T239N | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as COSV56514690; called by muse, mutect2, varscan2
- DST | c.17011A>C p.N5671H (on ENST00000361203 / NM_001374722.1; = p.N3368H on NM_015548.5) | Missense Mutation (SNP) | VAF 35/258 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55030566; called by muse, mutect2, varscan2
- ELAPOR2 | c.2703G>A p.W901* (on ENST00000450689 / NM_001142749.3; = p.W734* on NM_152748.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 12/175 reads (7%) | catalogued as COSV51889841; called by muse, mutect2
- ENOX1 | c.1162A>T p.S388C | Missense Mutation (SNP) | VAF 55/102 reads (54%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.841); catalogued as COSV54910368; called by muse, mutect2, varscan2
- EPHA3 | c.2282A>T p.K761M | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60718556; called by muse, mutect2
- EPHA5 | c.3053A>T p.K1018M | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV56661590; called by muse, mutect2, varscan2
- FAT3 | c.7514T>G p.V2505G | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV53116176, COSV53151630; called by muse, mutect2, varscan2
- FAT4 | c.5036G>T p.R1679L | Missense Mutation (SNP) | VAF 26/185 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV67884986, COSV67895089; called by muse, mutect2, varscan2
- FBN2 | c.4745A>C p.K1582T | Missense Mutation (SNP) | VAF 137/359 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.039); catalogued as COSV52532976; called by muse, mutect2, varscan2
- FGF9 | c.481C>T p.R161* | Nonsense Mutation (SNP) | VAF 25/68 reads (37%) | catalogued as COSV66644771, COSV66645128; called by muse, mutect2, varscan2
- FIGN | c.1424A>C p.E475A | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as COSV100291324, COSV100291527, COSV60769948; called by muse, mutect2, varscan2
- FMN2 | c.2845C>A p.P949T | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.993); catalogued as COSV60430674; called by muse, mutect2, varscan2
- GAD1 | c.757G>A p.A253T | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.149); catalogued as COSV60151756; called by muse, mutect2, varscan2
- GPR151 | c.257C>A p.S86Y | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.355); catalogued as COSV57040072; called by muse, mutect2, varscan2
- GRM8 | c.2123T>A p.L708H | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV58852473; called by muse, mutect2, varscan2
- GUCY1B1 | c.171A>C p.K57N | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.026); catalogued as COSV52377737; called by muse, mutect2, varscan2
- HFM1 | c.866T>G p.F289C | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV54033767; called by muse, mutect2, varscan2
- IGSF10 | c.2146A>T p.S716C | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.628); catalogued as COSV56789565; called by muse, mutect2, varscan2
- IL11RA | c.961C>G p.P321A | Missense Mutation (SNP) | VAF 12/428 reads (3%) | SIFT tolerated (0.32); PolyPhen benign (0.025); catalogued as COSV52405381; called by muse, mutect2
- INTS3 | c.893G>A p.R298Q | Missense Mutation (SNP) | VAF 22/598 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV59680305; called by muse, mutect2
- ISG20 | c.460G>C p.D154H | Missense Mutation (SNP) | VAF 48/258 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60144235; called by muse, varscan2
- KCNH5 | c.2611A>C p.S871R | Missense Mutation (SNP) | VAF 31/148 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.037); catalogued as COSV59770301; called by muse, mutect2, varscan2
- KCNH8 | c.703G>C p.V235L | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV60471743; called by muse, mutect2
- KIAA0753 | c.2811A>C p.E937D | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.471); catalogued as COSV63818316; called by muse, varscan2
- LRP1B | c.4363G>A p.D1455N | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV67191744; called by muse, mutect2, varscan2
- LRRC18 | c.35A>C p.K12T | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.922); catalogued as COSV53282559, COSV99631553; called by muse, mutect2, varscan2
- LRTM2 | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as rs781269529, COSV54566032; called by muse, mutect2, varscan2
- MDH1B | c.522A>C p.E174D | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.079); catalogued as COSV100982356, COSV65588444, COSV65588826; called by muse, mutect2, varscan2
- MMP25 | c.455A>C p.E152A | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as COSV60680600; called by muse, mutect2, varscan2
- MNAT1 | c.706G>C p.A236P | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.602); catalogued as COSV54194134; called by muse, mutect2, varscan2
- MPP7 | c.1219A>T p.R407* | Nonsense Mutation (SNP) | VAF 22/156 reads (14%) | catalogued as COSV61735866; called by muse, mutect2, varscan2
- MUC16 | c.34656T>G p.S11552R | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.608); catalogued as COSV67481524; called by muse, mutect2, varscan2
- MYBPC2 | c.2267A>G p.K756R | Missense Mutation (SNP) | VAF 53/125 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.178); catalogued as COSV63098334; called by muse, mutect2, varscan2
- MYH4 | c.554A>C p.K185T | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV55123338; called by muse, mutect2, varscan2
- MYT1 | c.2330G>A p.G777E | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60510611; called by muse, mutect2, varscan2
- NACC2 | c.1675T>C p.F559L | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.219); catalogued as COSV53201992; called by muse, mutect2, varscan2
- NCKAP5 | c.4096A>C p.S1366R | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.104); catalogued as rs757356901, COSV58445055; called by muse, mutect2, varscan2
- NECAP1 | c.115G>A p.D39N | Missense Mutation (SNP) | VAF 16/238 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.738); catalogued as COSV60250140; called by muse, mutect2
- NEGR1 | c.788A>C p.K263T | Missense Mutation (SNP) | VAF 29/144 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.266); catalogued as COSV60862089; called by muse, mutect2, varscan2
- NNT | c.2897C>A p.A966E | Missense Mutation (SNP) | VAF 28/314 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52928067; called by muse, mutect2
- NOP14 | c.1513C>A p.L505I | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.976); catalogued as COSV58626757; called by muse, mutect2, varscan2
- NOS3 | c.2525C>T p.P842L | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs920415717, COSV52493674; called by mutect2, varscan2
- NRK | c.1445A>G p.Q482R | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.188); catalogued as COSV54602677; called by muse, mutect2, varscan2
- OR10AD1 | c.205C>T p.L69F | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59612896; called by muse, mutect2, varscan2
- OR11H4 | c.142A>C p.T48P | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV59560700; called by muse, mutect2, varscan2
- OR4Q3 | c.873G>T p.L291F | Missense Mutation (SNP) | VAF 54/252 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV59179667; called by muse, mutect2, varscan2
- OR5T1 | c.275A>G p.K92R | Missense Mutation (SNP) | VAF 33/147 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as COSV57304015; called by muse, varscan2
- OTOF | c.5242G>A p.D1748N (on ENST00000272371 / NM_194248.3; = p.D981N on NM_004802.4) | Missense Mutation (SNP) | VAF 77/316 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV55512521; called by muse, mutect2, varscan2
- PAPPA | c.3699C>A p.Y1233* | Nonsense Mutation (SNP) | VAF 20/96 reads (21%) | catalogued as COSV60288991; called by muse, mutect2, varscan2
- PCDH11X | c.749A>G p.K250R | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV53490826, COSV53497035; called by muse, mutect2
- PCDH11X | c.2191G>A p.G731S | Missense Mutation (SNP) | VAF 135/187 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100007924; called by muse, mutect2, varscan2
- PCDHA6 | c.1376A>G p.E459G | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.483); catalogued as COSV65346260; called by muse, mutect2, varscan2
- PHF19 | c.1642C>T p.R548W | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65878756; called by muse, mutect2, varscan2
- PKHD1 | c.10687T>G p.L3563V | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.62); PolyPhen benign (0.006); catalogued as COSV64396345; called by muse, mutect2, varscan2
- PRAMEF18 | c.457G>A p.V153I | Missense Mutation (SNP) | VAF 201/747 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.053); catalogued as rs1360340065; called by muse, varscan2
- RGS18 | c.51A>C p.K17N | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV66509395; called by muse, mutect2
- ROBO1 | c.3947G>T p.G1316V | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV71397147; called by muse, mutect2
- RORA | c.1076-1G>A p.X359_splice (on ENST00000335670 / NM_134261.3; = p.X384_splice on NM_002943.3) | Splice Site (SNP) | VAF 18/362 reads (5%) | catalogued as COSV55042493; called by muse, mutect2
- RXFP3 | c.130C>T p.Q44* | Nonsense Mutation (SNP) | VAF 18/188 reads (10%) | catalogued as COSV57507181; called by muse, mutect2, varscan2
- RYR2 | c.7187T>G p.I2396S | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV63703003; called by muse, mutect2, varscan2
- SCUBE2 | c.781G>C p.E261Q | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.724); catalogued as rs764067359, COSV58545414; called by muse, mutect2
- SEL1L | c.2333G>A p.R778Q | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.278); catalogued as rs376067391, COSV60921719; called by muse, mutect2, varscan2
- SEMA6D | c.1350A>T p.K450N | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60381464; called by muse, mutect2, varscan2
- SFMBT2 | c.2098G>A p.V700M | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs374674288; called by muse, mutect2, varscan2
- SIPA1L2 | c.3528C>G p.S1176R | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.62); PolyPhen benign (0.022); catalogued as rs998363079, COSV53396032; called by muse, mutect2, varscan2
- SLC29A4 | c.979G>A p.V327M | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.301); catalogued as rs778220755, COSV51875992; called by muse, mutect2, varscan2
- SLC9A3 | c.766G>A p.V256M | Missense Mutation (SNP) | VAF 33/132 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs534607238, COSV53803604; called by muse, mutect2, varscan2
- SPACA1 | c.458T>G p.L153R | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.804); catalogued as COSV99389374; called by muse, mutect2, varscan2
- SPAG17 | c.910A>T p.N304Y | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60464328; called by muse, mutect2, varscan2
- SPEF2 | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 17/172 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs528551876, COSV56798299; called by muse, mutect2, varscan2
- SRRM2 | c.4171G>A p.V1391M | Missense Mutation (SNP) | VAF 32/520 reads (6%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.003); catalogued as rs774617018, COSV57078154; called by muse, mutect2
- SSH2 | c.2686C>T p.R896C | Missense Mutation (SNP) | VAF 56/370 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs763639780, COSV52173664; called by muse, mutect2, varscan2
- TAFA2 | c.346T>C p.W116R | Missense Mutation (SNP) | VAF 33/154 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV69176794; called by muse, mutect2, varscan2
- TENM4 | c.4694A>C p.K1565T | Missense Mutation (SNP) | VAF 44/141 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1437112114, COSV53653830, COSV99572844; called by muse, mutect2, varscan2
- THSD7A | c.2810A>T p.K937I | Missense Mutation (SNP) | VAF 31/218 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV70269594; called by muse, mutect2, varscan2
- TMPRSS11D | c.1153G>A p.G385R | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52225086; called by mutect2, varscan2
- TNRC6C | c.3843G>T p.M1281I | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV56950233; called by muse, mutect2, varscan2
- TRIM60 | c.1059A>C p.E353D | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as COSV61971338; called by muse, mutect2, varscan2
- TRPM7 | c.2533T>G p.F845V | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.47); PolyPhen benign (0.094); catalogued as COSV57919826; called by muse, mutect2, varscan2
- TTN | c.50290C>T p.R16764C (on ENST00000591111; = p.R9340C on NM_003319.4) | Missense Mutation (SNP) | VAF 19/107 reads (18%) | PolyPhen probably damaging (0.998); catalogued as rs199656264, COSV60248379; called by muse, mutect2, varscan2
- TTN | c.42572G>T p.R14191L (on ENST00000591111; = p.R6767L on NM_003319.4) | Missense Mutation (SNP) | VAF 17/105 reads (16%) | PolyPhen probably damaging (0.998); catalogued as COSV60231963; called by muse, mutect2, varscan2
- TTN | c.17809T>G p.F5937V (on ENST00000591111; = p.F5010V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/122 reads (10%) | PolyPhen benign (0.194); catalogued as COSV60232016; called by muse, mutect2
- VPS13B | c.10081T>G p.F3361V | Missense Mutation (SNP) | VAF 46/955 reads (5%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs748996302, COSV62151912; called by muse, mutect2
- VSTM1 | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.033); catalogued as rs748323530, COSV58076064; called by muse, mutect2, varscan2
- WDR59 | c.1561C>T p.R521W | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs773498234, COSV50935534; called by muse, mutect2, varscan2
- WDR90 | c.4690A>G p.S1564G | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.13); catalogued as COSV53473306; called by muse, mutect2, varscan2
- WIPF2 | c.904G>T p.A302S | Missense Mutation (SNP) | VAF 15/374 reads (4%) | SIFT tolerated (0.49); PolyPhen benign (0.058); catalogued as COSV60274923, COSV60276105; called by muse, mutect2
- XPNPEP1 | c.131T>G p.M44R | Missense Mutation (SNP) | VAF 17/157 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV100450766; called by muse, mutect2, varscan2
- XPNPEP1 | c.130A>T p.M44L | Missense Mutation (SNP) | VAF 17/157 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.494); catalogued as COSV100450768; called by muse, mutect2, varscan2
- XRCC5 | c.1558G>A p.A520T | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs761811665, COSV67537279, COSV99060769; called by muse, mutect2, varscan2
- ZFHX3 | c.10831del p.H3611Tfs*83 | Frame Shift Del (DEL) | VAF 4/22 reads (18%) | catalogued as COSV51720325; called by mutect2, pindel, varscan2
- ZNF407 | c.327T>G p.D109E | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV55263400; called by muse, mutect2, varscan2
- ZNF85 | c.1341T>G p.I447M | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1405531404, COSV60214436; called by muse, mutect2
- ZNF98 | c.1106A>C p.K369T | Missense Mutation (SNP) | VAF 30/47 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs753329243, COSV63338503; called by mutect2, varscan2
- PRAMEF19 | c.457G>A p.V153I | Missense Mutation (SNP) | VAF 40/520 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.051); called by muse, mutect2
- TRIP12 | c.2195+2_2195+28del p.X732_splice | Splice Site (DEL) | VAF 12/66 reads (18%) | called by mutect2, pindel
- ZWINT | c.769del p.R257Efs*18 | Frame Shift Del (DEL) | VAF 25/182 reads (14%) | called by mutect2, pindel, varscan2
- AFF3 | c.723A>G p.Q241= | Silent (SNP) | VAF 13/82 reads (16%) | catalogued as COSV57865358; called by muse, mutect2, varscan2
- AGXT2 | c.51C>T p.S17= | Silent (SNP) | VAF 51/79 reads (65%) | catalogued as rs144847973; called by muse, mutect2, varscan2
- AP5M1 | c.141A>G p.E47= | Silent (SNP) | VAF 13/92 reads (14%) | catalogued as COSV55106367; called by muse, mutect2, varscan2
- ATG16L2 | c.447G>A p.Q149= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as COSV58362536; called by muse, mutect2, varscan2
- CDH4 | c.744C>T p.H248= | Silent (SNP) | VAF 17/125 reads (14%) | catalogued as rs753827955, COSV64659999; called by muse, mutect2, varscan2
- CLVS1 | c.345T>C p.D115= | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as COSV57979965; called by muse, mutect2, varscan2
- CPQ | c.306A>G p.K102= | Silent (SNP) | VAF 8/81 reads (10%) | catalogued as rs781314881, COSV55152049, COSV55154980; called by muse, mutect2
- CST2 | c.417A>G p.Q139= | Silent (SNP) | VAF 22/131 reads (17%) | catalogued as rs1482823977, COSV59031586; called by muse, mutect2, varscan2
- DNER | c.1569C>G p.L523= | Silent (SNP) | VAF 13/105 reads (12%) | catalogued as COSV59172212; called by muse, mutect2, varscan2
- FAM168A | c.558C>T p.A186= (on ENST00000064778 / NM_001286050.2; = p.A177= on NM_015159.3) | Silent (SNP) | VAF 45/142 reads (32%) | catalogued as rs761937954, COSV50359303; called by muse, mutect2, varscan2
- FAT3 | c.7278T>C p.F2426= | Silent (SNP) | VAF 11/92 reads (12%) | catalogued as rs1318763182, COSV53151607; called by muse, mutect2, varscan2
- FER | c.1638G>T p.L546= | Silent (SNP) | VAF 20/97 reads (21%) | catalogued as COSV99811481; called by muse, mutect2, varscan2
- FER | c.1639C>T p.L547= | Silent (SNP) | VAF 19/97 reads (20%) | catalogued as COSV99811484; called by muse, mutect2, varscan2
- FSHR | c.456A>G p.Q152= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as rs565745010, COSV58620371, COSV58630305; called by muse, mutect2, varscan2
- GIPR | c.246G>A p.A82= | Silent (SNP) | VAF 38/172 reads (22%) | catalogued as COSV54423708; called by muse, mutect2, varscan2
- GREM2 | c.438C>G p.L146= | Silent (SNP) | VAF 6/98 reads (6%) | catalogued as rs954972055, COSV58955048; called by muse, mutect2
- IGSF1 | c.864C>T p.I288= | Silent (SNP) | VAF 21/160 reads (13%) | catalogued as COSV63838974, COSV63839521; called by muse, mutect2, varscan2
- KIAA0825 | c.741A>T p.T247= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as COSV56956735; called by muse, mutect2, varscan2
- MAGEB6 | c.126A>C p.S42= | Silent (SNP) | VAF 21/52 reads (40%) | catalogued as COSV66872719; called by muse, mutect2, varscan2
- MICAL3 | c.2673C>T p.I891= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as rs745600484, COSV52902442, COSV99259711; called by muse, mutect2, varscan2
- MSL2 | c.237T>G p.P79= | Silent (SNP) | VAF 48/248 reads (19%) | catalogued as COSV53868300; called by muse, mutect2, varscan2
- MUC16 | c.2898T>A p.T966= | Silent (SNP) | VAF 128/315 reads (41%) | catalogued as COSV67481527; called by muse, mutect2, varscan2
- MUC3A | c.8529A>T p.S2843= | Silent (SNP) | VAF 40/312 reads (13%) | catalogued as COSV100113917; called by muse, mutect2, varscan2
- NGFR | c.1053C>G p.L351= | Silent (SNP) | VAF 75/139 reads (54%) | catalogued as COSV50803504; called by muse, mutect2, varscan2
- NIPSNAP3A | c.231T>C p.F77= | Silent (SNP) | VAF 19/272 reads (7%) | catalogued as COSV66113591; called by muse, mutect2
- NLRP10 | c.855G>A p.T285= | Silent (SNP) | VAF 69/131 reads (53%) | catalogued as rs765306454, COSV60781541; called by muse, mutect2, varscan2
- NPAP1 | c.522C>T p.D174= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as rs368120585, COSV100274980; called by muse, mutect2, varscan2
- OR2M5 | c.639C>A p.I213= | Silent (SNP) | VAF 51/452 reads (11%) | catalogued as COSV63546761; called by muse, mutect2, varscan2
- OR5T1 | c.837T>G p.T279= | Silent (SNP) | VAF 38/252 reads (15%) | catalogued as rs1202560100, COSV57302542, COSV57304590; called by muse, mutect2, varscan2
- ORC4 | c.306G>A p.L102= | Silent (SNP) | VAF 8/65 reads (12%) | catalogued as COSV51575893; called by muse, mutect2, varscan2
- PCDHA9 | c.1353C>T p.N451= | Silent (SNP) | VAF 39/119 reads (33%) | catalogued as rs1554143388, COSV65324575; called by muse, mutect2, varscan2
- PCLO | c.7617T>G p.T2539= | Silent (SNP) | VAF 47/113 reads (42%) | catalogued as COSV61654290; called by muse, mutect2, varscan2
- PEG3 | c.2034T>G p.T678= | Silent (SNP) | VAF 29/142 reads (20%) | catalogued as COSV55642079, COSV99690435; called by muse, mutect2, varscan2
- PGAP6 | c.405C>T p.T135= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs1236941757, COSV99170572; called by muse, mutect2
- PLA2G12B | c.81G>A p.T27= | Silent (SNP) | VAF 28/399 reads (7%) | catalogued as rs752264456, COSV65978477; called by muse, mutect2
- PRDM14 | c.276G>T p.L92= | Silent (SNP) | VAF 59/70 reads (84%) | catalogued as rs766237068, COSV52574441; called by muse, mutect2, varscan2
- PROX2 | c.1725G>A p.S575= (on ENST00000556489 / NM_001243007.1; = p.S348= on NM_001080408.2) | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as rs764899107, COSV71519996; called by muse, mutect2, varscan2
- RFX2 | c.384C>T p.P128= | Silent (SNP) | VAF 16/87 reads (18%) | catalogued as COSV57944095; called by muse, mutect2, varscan2
- SEC23B | c.1926C>T p.S642= | Silent (SNP) | VAF 18/143 reads (13%) | catalogued as COSV52722555; called by muse, mutect2, varscan2
- SLC38A4 | c.744C>A p.P248= | Silent (SNP) | VAF 32/147 reads (22%) | catalogued as COSV56969811; called by muse, mutect2, varscan2
- SLITRK1 | c.972G>T p.A324= | Silent (SNP) | VAF 6/62 reads (10%) | catalogued as COSV65674393, COSV65676911; called by mutect2, varscan2
- SLITRK3 | c.966T>G p.S322= | Silent (SNP) | VAF 53/279 reads (19%) | catalogued as COSV53851461; called by muse, mutect2, varscan2
- THADA | c.1078T>C p.L360= | Silent (SNP) | VAF 59/161 reads (37%) | catalogued as COSV57689655; called by muse, mutect2, varscan2
- TTN | c.25512C>T p.F8504= (on ENST00000591111; = p.F7577= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/160 reads (13%) | catalogued as rs551600321, COSV59960811; ClinVar: likely benign; called by muse, mutect2, varscan2
- USH2A | c.3669T>C p.C1223= | Silent (SNP) | VAF 15/83 reads (18%) | catalogued as COSV56408976; called by muse, mutect2, varscan2
- ZNF334 | c.1161C>T p.F387= | Silent (SNP) | VAF 19/312 reads (6%) | catalogued as COSV61619631; called by muse, mutect2
- KMT5C | c.570+683G>A | Intron (SNP) | VAF 4/14 reads (29%) | catalogued as rs1177470666, COSV99726046; called by muse, mutect2, varscan2
- OR2W5 | n.1215A>C | RNA (SNP) | VAF 58/137 reads (42%) | called by muse, mutect2, varscan2
